Somatic mutation profile of tumor specimen HCM-WCMC-1285-C54-01A (aliquot HCM-WCMC-1285-C54-01A-10D-A937-36) from HCMI case HCM-WCMC-1285-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G2; Age at diagnosis: 34.0 years (12,423 days).
Specimen HCM-WCMC-1285-C54-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbde0226-9603-4742-968d-7bd3f30c78a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1285-C54-10A (Blood Derived Normal), aliquot HCM-WCMC-1285-C54-10A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52d3001b-d59a-489a-9469-acb71fcaa215

The open-access MAF lists 1,224 somatic variants for this specimen: 876 protein-altering or splice-affecting, 308 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 691, Silent 308, Frame Shift Del 92, Nonsense Mutation 45, Frame Shift Ins 33, Intron 27, In Frame Del 6, 3'Flank 5, Splice Site 5, Splice Region 4, RNA 2, 5'UTR 2.

Variants (750 of 1,224; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6230G>A p.R2077Q | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886044759, CM1311152; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 30/284 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1057519728, COSV61068605, COSV61070825, COSV61071840; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5617C>T p.R1873W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397516321, CM064133; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NIPBL | c.5167C>T p.R1723* | Nonsense Mutation (SNP) | VAF 69/480 reads (14%) | catalogued as rs121918267, CM042514, COSV56952714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAX2 | c.76del p.V26Cfs*3 | Frame Shift Del (DEL) | VAF 34/186 reads (18%) | catalogued as rs75462234, COSV62291007; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 38/278 reads (14%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3R2 | c.1681A>G p.N561D | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1057519801, COSV55847533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 177/634 reads (28%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RNF43 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 50/276 reads (18%) | hotspot (GDC flag); catalogued as rs771831816, COSV68457398; called by muse, mutect2, varscan2
- ABCC8 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 43/245 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1057523131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD10 | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 46/898 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs748865561; called by muse, mutect2
- ABI3BP | c.2246C>T p.P749L | Missense Mutation (SNP) | VAF 28/500 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99428732; called by muse, mutect2
- AC008397.2 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 36/233 reads (15%) | catalogued as rs780245468; called by muse, mutect2, varscan2
- ACACB | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs978164597, COSV100622284; called by muse, varscan2
- ACIN1 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 17/543 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV52975597; called by muse, mutect2
- ACSL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 58/352 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762658676, COSV55663671; called by muse, mutect2, varscan2
- ACSL6 | c.1588C>A p.L530M (on ENST00000379240; = p.L555M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57298860; called by muse, mutect2
- ACVR1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 72/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as CM091422, COSV99717598; called by muse, mutect2, varscan2
- ADAMTS12 | c.4070C>T p.A1357V | Missense Mutation (SNP) | VAF 47/329 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV61270540, COSV61286757; called by muse, mutect2, varscan2
- ADAMTS18 | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 59/359 reads (16%) | catalogued as rs775431905, COSV51417329; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 38/260 reads (15%) | catalogued as COSV65879385; called by mutect2, varscan2
- ADSS1 | c.863del p.P288Rfs*4 | Frame Shift Del (DEL) | VAF 41/236 reads (17%) | catalogued as rs1566801565, COSV58275931; called by mutect2, varscan2
- AGO2 | c.1806dup p.A603Rfs*71 | Frame Shift Ins (INS) | VAF 38/237 reads (16%) | catalogued as rs748399150; called by mutect2, varscan2
- AHCY | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.506); catalogued as rs1021875336; called by muse, mutect2, varscan2
- AL121899.2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1368754825; called by muse, mutect2, varscan2
- ALPP | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67396129; called by muse, mutect2, varscan2
- ANKRD11 | c.6704C>T p.P2235L | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1394383095, COSV56359939, COSV56370923; ClinVar: uncertain significance; called by muse, mutect2
- ANKRD18A | c.844del p.R282Efs*11 | Frame Shift Del (DEL) | VAF 47/260 reads (18%) | catalogued as rs1563970981; called by mutect2, varscan2
- ANKRD24 | c.2905C>T p.R969C | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs867343383, COSV53671969; called by muse, mutect2
- ANKRD30A | c.584del p.N195Mfs*26 (on ENST00000611781; = p.N139Mfs*26 on NM_052997.2) | Frame Shift Del (DEL) | VAF 37/316 reads (12%) | catalogued as COSV64613285; called by mutect2, varscan2
- ARFGAP1 | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (1); catalogued as rs1008965738; called by muse, mutect2, varscan2
- ARHGEF40 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.46); catalogued as rs373963892; called by muse, mutect2, varscan2
- ARID1A | c.4052G>A p.G1351D | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100249873; called by muse, mutect2, varscan2
- ARID1A | c.4534C>T p.Q1512* | Nonsense Mutation (SNP) | VAF 52/204 reads (25%) | catalogued as COSV61373983; called by muse, varscan2
- ATF6B | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 43/301 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as rs753618773; called by muse, mutect2, varscan2
- ATG4D | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 29/231 reads (13%) | catalogued as rs142082988; called by muse, mutect2, varscan2
- ATP1B2 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs372597402; called by muse, mutect2, varscan2
- ATP5MG | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 66/366 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs200472961; called by muse, mutect2, varscan2
- ATP6V0C | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs1321416008; called by muse, mutect2, varscan2
- ATXN10 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 69/493 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs1042452273, COSV53298989, COSV99426550; called by muse, mutect2, varscan2
- AUTS2 | c.3086C>T p.T1029M | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as rs755394081; called by muse, mutect2, varscan2
- B3GNT3 | c.650C>G p.T217R | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57952871; called by muse, mutect2, varscan2
- BACH1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 70/476 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1250115670; called by muse, varscan2
- BBS9 | c.1561C>T p.R521* (on ENST00000242067 / NM_001348036.1; = p.R481* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/396 reads (14%) | catalogued as rs748601675, COSV54157359; called by muse, mutect2, varscan2
- BCKDK | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs749467687; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL6 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); catalogued as rs1468858377, COSV51653748; called by muse, mutect2, varscan2
- BCL7C | c.617del p.P206Hfs*36 | Frame Shift Del (DEL) | VAF 32/188 reads (17%) | catalogued as rs754078059; called by mutect2, varscan2
- BDH1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768985550, COSV100827129; called by muse, mutect2
- BIRC6 | c.8708C>T p.P2903L | Missense Mutation (SNP) | VAF 92/538 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs192943089; called by muse, mutect2, varscan2
- BIRC6 | c.10810G>A p.A3604T | Missense Mutation (SNP) | VAF 78/337 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs369960712, COSV70204867; called by muse, mutect2, varscan2
- BMP8B | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs137876639; called by muse, mutect2, varscan2
- BPIFB1 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs1340556429; called by muse, mutect2, varscan2
- BRF1 | c.1378-6G>A | Splice Region (SNP) | VAF 19/253 reads (8%) | catalogued as rs587682422, COSV59266325; called by muse, mutect2
- BRPF3 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs371915331; called by muse, mutect2, varscan2
- BRWD1 | c.3919del p.S1307Afs*19 | Frame Shift Del (DEL) | VAF 63/352 reads (18%) | catalogued as rs1296036169; called by mutect2, varscan2
- C10orf120 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1240570346; called by muse, mutect2, varscan2
- C14orf132 | c.251G>A p.R84Q (on ENST00000553782 / NM_001289139.2; = p.R53Q on NM_001252507.3) | Missense Mutation (SNP) | VAF 56/272 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs1188567084; called by muse, varscan2
- C19orf67 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs553160046; called by muse, mutect2, varscan2
- C1QTNF6 | c.618del p.Y206* | Frame Shift Del (DEL) | VAF 29/259 reads (11%) | catalogued as COSV99742368; called by mutect2, varscan2
- C20orf194 | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs374809056; called by muse, mutect2, varscan2
- C3 | c.4594C>T p.R1532W | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199911426; called by muse, mutect2, varscan2
- C8orf82 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV52766720; called by muse, mutect2, varscan2
- CACNA1B | c.4412C>T p.P1471L | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs200167577, COSV53142521, COSV99495922; called by muse, mutect2, varscan2
- CACNA1F | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1234852260; called by muse, mutect2, varscan2
- CACNA1G | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1174908448, COSV61732475; called by muse, varscan2
- CACNA1S | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 31/333 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs150646872; called by muse, mutect2
- CASKIN1 | c.2480C>T p.P827L | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1471502766; called by muse, mutect2, varscan2
- CASKIN2 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs374772637; called by muse, mutect2, varscan2
- CASP14 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55664922; called by muse, mutect2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 26/219 reads (12%) | catalogued as rs931648756, COSV51845077; called by muse, mutect2, varscan2
- CAVIN2 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 67/305 reads (22%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.007); catalogued as rs766866506, COSV58423322; called by muse, mutect2, varscan2
- CCAR1 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs759599293; called by muse, varscan2
- CCDC116 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs201583912; called by muse, mutect2, varscan2
- CCDC146 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs909346926; called by muse, mutect2
- CCDC185 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.445); catalogued as COSV100838845; called by muse, mutect2
- CCDC51 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs553082516; called by muse, mutect2, varscan2
- CCDC87 | c.1441dup p.M481Nfs*4 | Frame Shift Ins (INS) | VAF 43/275 reads (16%) | catalogued as rs1251984014; called by mutect2, varscan2
- CCER1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs1412453346; called by muse, mutect2
- CD300LG | c.651dup p.M218Hfs*21 | Frame Shift Ins (INS) | VAF 30/179 reads (17%) | catalogued as rs760923345; called by mutect2, varscan2
- CDH23 | c.3251G>A p.G1084D | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as rs754122678; called by muse, mutect2, varscan2
- CDHR2 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 46/185 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs745537051; called by muse, mutect2, varscan2
- CENPB | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1372115231, COSV60150573; called by muse, mutect2, varscan2
- CENPN | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 39/364 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100001136; called by muse, varscan2
- CEP120 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 103/564 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60265780; called by muse, mutect2, varscan2
- CES4A | c.1372G>A p.V458I (on ENST00000648724 / NM_001364782.1; = p.V360I on NM_001190201.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/251 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs1038431195, COSV58651594; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 29/204 reads (14%) | catalogued as rs1274191949; called by mutect2, varscan2
- CFH | c.1926G>T p.K642N | Missense Mutation (SNP) | VAF 25/518 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV66410353; called by muse, mutect2
- CHD4 | c.3445C>T p.R1149W (on ENST00000357008 / NM_001363606.2; = p.R1162W on NM_001273.5) | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58894467; called by muse, mutect2, varscan2
- CHRNB3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs576780909, COSV51494948; called by muse, mutect2
- CIC | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV73907326; called by muse, varscan2
- CKAP5 | c.5387G>A p.R1796Q (on ENST00000529230 / NM_001008938.4; = p.R1736Q on NM_014756.3) | Missense Mutation (SNP) | VAF 77/442 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs758663989; called by muse, mutect2, varscan2
- CLCNKA | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs200446764; called by muse, mutect2, varscan2
- CNGB1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs369288085; called by muse, mutect2, varscan2
- CNTNAP5 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs779684862; called by muse, mutect2, varscan2
- CNTNAP5 | c.2374G>A p.A792T | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs1425252476, COSV70487458; called by muse, mutect2, varscan2
- COL25A1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 58/454 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960016417, COSV67651331; called by muse, mutect2, varscan2
- COL2A1 | c.3137del p.P1046Lfs*84 | Frame Shift Del (DEL) | VAF 34/168 reads (20%) | catalogued as CD063500; called by mutect2, varscan2
- CORO6 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1242132064, COSV100801156; called by muse, mutect2, varscan2
- CP | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 76/393 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1056623509, CM148239, COSV52834538; called by muse, mutect2, varscan2
- CPA2 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs751540588, COSV55980371; called by muse, mutect2, varscan2
- CSMD1 | c.5293C>T p.R1765* (on ENST00000520002; = p.R1764* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 45/350 reads (13%) | catalogued as COSV59298786; called by muse, mutect2, varscan2
- CSMD2 | c.4801G>T p.G1601W | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53934422; called by muse, mutect2, varscan2
- CTBP2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs1194942389, COSV58338413; called by muse, mutect2, varscan2
- CWH43 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as rs1560489772; called by muse, mutect2
- CYP2A13 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57836938; called by muse, mutect2, varscan2
- CYP4F12 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.204); catalogued as rs1045250790, COSV61173169; called by muse, mutect2, varscan2
- DAB2IP | c.1768C>T p.R590C (on ENST00000408936; = p.R562C on NM_032552.3) | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); catalogued as rs766959002, COSV52257062; called by muse, varscan2
- DCHS2 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1302134798, COSV59727308; called by muse, varscan2
- DDX5 | c.1018_1020del p.K340del | In Frame Del (DEL) | VAF 49/404 reads (12%) | catalogued as rs1555671300; called by mutect2, varscan2
- DGKD | c.1370G>A p.R457Q (on ENST00000264057 / NM_152879.3; = p.R413Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs866444573; called by muse, mutect2
- DIO2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1490426699; called by muse, varscan2
- DIP2A | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs368502145; called by muse, mutect2, varscan2
- DLL1 | c.1382G>A p.G461D | Missense Mutation (SNP) | VAF 65/303 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.794); catalogued as rs1039024205; called by muse, mutect2, varscan2
- DNAH2 | c.7058C>T p.T2353M | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs145304537; called by muse, mutect2, varscan2
- DNAH5 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 61/418 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs755574532, COSV54233163; called by muse, mutect2, varscan2
- DNAJC16 | c.1680C>T p.S560= | Splice Region (SNP) | VAF 36/217 reads (17%) | catalogued as rs148700636; called by muse, mutect2, varscan2
- DNAJC16 | c.2169A>G p.I723M | Missense Mutation (SNP) | VAF 82/480 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs778529647; called by muse, mutect2, varscan2
- DNAJC5 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs139312819; ClinVar: uncertain significance; called by muse, varscan2
- DNM1L | c.2191C>T p.R731W (on ENST00000549701 / NM_012062.5; = p.R694W on NM_005690.4) | Missense Mutation (SNP) | VAF 67/449 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750745310; called by muse, mutect2, varscan2
- DNMT3A | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.636); catalogued as rs200559311; called by muse, mutect2, varscan2
- DNMT3A | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.132); catalogued as rs746009417, COSV53049060, COSV53053091; called by muse, mutect2, varscan2
- DNTT | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775903509, COSV100960775; called by muse, varscan2
- DOT1L | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as rs371142941; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); catalogued as rs267601226; called by muse, mutect2, varscan2
- DUSP8 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs1202525328; called by muse, mutect2, varscan2
- DYNC2H1 | c.9020G>A p.R3007H | Missense Mutation (SNP) | VAF 80/627 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as rs1261435614, COSV62098513; called by muse, mutect2, varscan2
- ECE1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1305763532, COSV51662368; called by muse, mutect2, varscan2
- EFTUD2 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764767656, COSV68182081; called by muse, mutect2, varscan2
- EGLN3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99164386; called by muse, mutect2, varscan2
- ELAVL2 | c.656A>G p.Y219C | Missense Mutation (SNP) | VAF 67/471 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs753913440; called by muse, mutect2, varscan2
- ELOVL7 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749088345, COSV70917986; called by muse, mutect2
- ENTPD6 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs747725682; called by muse, mutect2, varscan2
- ENTPD7 | c.1181A>G p.N394S | Missense Mutation (SNP) | VAF 52/411 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as rs1364988564; called by muse, mutect2, varscan2
- ERGIC3 | c.80del p.G27Afs*4 | Frame Shift Del (DEL) | VAF 30/193 reads (16%) | catalogued as COSV54141087; called by mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 156/461 reads (34%) | catalogued as rs775950025; called by mutect2, varscan2
- EXTL3 | c.2077G>A p.V693M | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1018298399; called by muse, mutect2, varscan2
- FAAP100 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs774743717; called by muse, mutect2, varscan2
- FAM120B | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 59/438 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775606266, COSV99378764; called by muse, mutect2, varscan2
- FAM163B | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); catalogued as rs780818543, COSV100618914; called by muse, varscan2
- FAM171B | c.2467A>T p.I823F | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1304871872; called by muse, mutect2, varscan2
- FAM184A | c.1530+1G>A p.X510_splice | Splice Site (SNP) | VAF 36/181 reads (20%) | catalogued as rs545433444; called by muse, mutect2, varscan2
- FAM83B | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs376026026; called by muse, mutect2, varscan2
- FARP2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs199738844; called by muse, mutect2, varscan2
- FBF1 | c.2870G>A p.R957Q (on ENST00000586717; = p.R972Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs553617516; called by muse, mutect2, varscan2
- FBN2 | c.7204C>T p.R2402C | Missense Mutation (SNP) | VAF 86/516 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); catalogued as rs916476326, COSV52505801, COSV52548116; called by muse, mutect2, varscan2
- FBRSL1 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1242690170; called by muse, mutect2, varscan2
- FGF11 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs530767669; called by muse, mutect2, varscan2
- FLOT1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 16/535 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs754804649; called by muse, mutect2
- FNBP4 | c.2863C>T p.R955C | Missense Mutation (SNP) | VAF 58/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs763833197; called by muse, mutect2, varscan2
- FRMPD3 | c.3039del p.S1014Afs*18 | Frame Shift Del (DEL) | VAF 45/217 reads (21%) | catalogued as rs752351689; called by mutect2, varscan2
- GABBR1 | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 91/517 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.286); catalogued as rs757008467, COSV63540730; called by muse, mutect2, varscan2
- GAREM1 | c.1949A>G p.Y650C (on ENST00000269209 / NM_001242409.2; = p.Y649C on NM_022751.3) | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99330405; called by muse, mutect2
- GAS6 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs765354911; called by muse, mutect2, varscan2
- GBE1 | c.263G>A p.C88Y | Missense Mutation (SNP) | VAF 114/624 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1042498; called by muse, mutect2, varscan2
- GDPD4 | c.1632G>T p.K544N | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100264965; called by muse, mutect2, varscan2
- GFOD1 | c.848C>T p.T283M | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs763168816, COSV64955232; called by muse, mutect2, varscan2
- GIPC2 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 15/353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1488814325, COSV66127627; called by muse, mutect2
- GNAS | c.217G>A p.G73S | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.595); catalogued as rs587778380; ClinVar: not provided; called by muse, mutect2, varscan2
- GOLGA2 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs994662451; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 40/228 reads (18%) | catalogued as rs370114090; called by mutect2, varscan2
- GRIK3 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as COSV66140701; called by mutect2, varscan2
- GRIK4 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs779846238, COSV70800239; called by muse, mutect2, varscan2
- GRIN2C | c.1807G>A p.V603M | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1378331673, COSV99500900; called by muse, mutect2, varscan2
- GRM1 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51151334; called by muse, mutect2, varscan2
- GZF1 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1041287600, COSV57637855; called by muse, varscan2
- HABP2 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1158919820; called by muse, mutect2
- HACE1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 48/806 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs771798096, COSV53499112; called by muse, mutect2
- HAUS6 | c.1636A>G p.R546G | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs1336288456; called by muse, mutect2, varscan2
- HAUS7 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs1556982166; called by muse, mutect2
- HBP1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 81/466 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99753595; called by muse, mutect2, varscan2
- HDHD3 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199715854; called by muse, mutect2, varscan2
- HGD | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99381375; called by muse, mutect2
- HLA-DQA2 | c.110A>C p.N37T | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs1343315131; called by muse, mutect2
- HNRNPM | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1450635900, COSV55312788; called by muse, mutect2
- HOOK1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 55/575 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs368144967; called by muse, mutect2
- HOXB1 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs768410617, COSV53317738; called by muse, mutect2, varscan2
- HROB | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.04); catalogued as rs762383052; called by muse, mutect2
- HSPB3 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 53/510 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs772793581; called by muse, mutect2, varscan2
- HTT | c.6596C>T p.A2199V | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs750741890; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 46/313 reads (15%) | catalogued as rs747841314; called by mutect2, varscan2
- IGSF9B | c.1260dup p.Y421Lfs*60 | Frame Shift Ins (INS) | VAF 26/120 reads (22%) | catalogued as rs775604395; called by mutect2, varscan2
- IK | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as rs367909137, COSV70257699; called by muse, mutect2, varscan2
- IL10 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 54/431 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs755490123, COSV65594355; called by muse, mutect2, varscan2
- IMPDH2 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | catalogued as rs761159150, COSV58247168; called by muse, varscan2
- INHBA | c.876C>A p.F292L | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99637251; called by muse, varscan2
- INPPL1 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1006478277, COSV53357512; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 42/212 reads (20%) | catalogued as rs760925109; called by mutect2, varscan2
- IQCK | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs560311228, COSV57521975; called by muse, mutect2, varscan2
- IQGAP1 | c.4477C>T p.R1493W | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs768558979; called by muse, mutect2, varscan2
- IQSEC1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56229085; called by muse, mutect2, varscan2
- ITGB8 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs767838901; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1250G>A p.R417H | Missense Mutation (SNP) | VAF 44/272 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs759664422; called by muse, mutect2, varscan2
- JADE1 | c.2135G>A p.G712D | Missense Mutation (SNP) | VAF 16/415 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.107); catalogued as COSV56905731; called by muse, mutect2
- JAKMIP2 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 15/385 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs1228466489, COSV54618000; called by muse, mutect2
- JPH2 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV65904077; called by muse, varscan2
- JPH3 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs759077257, COSV104370505; called by mutect2, varscan2
- KAT14 | c.488dup p.L163Ffs*5 | Frame Shift Ins (INS) | VAF 30/222 reads (14%) | catalogued as rs1480801806; called by mutect2, varscan2
- KATNB1 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65559604; called by muse, mutect2, varscan2
- KATNIP | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs767622231; called by muse, mutect2, varscan2
- KBTBD6 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs61999308; called by muse, mutect2, varscan2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 48/272 reads (18%) | catalogued as rs754892524; called by mutect2, varscan2
- KCNA4 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1221863870, COSV100068956; called by muse, mutect2, varscan2
- KCNC2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54371719; called by muse, mutect2
- KCNC4 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs765248480, COSV63924979; called by muse, varscan2
- KCNMA1 | c.1408G>A p.V470I | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.658); catalogued as rs149000684, COSV54266518; called by muse, mutect2, varscan2
- KCNMA1 | c.1306G>A p.V436I | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.956); catalogued as rs762346849, COSV54259883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1B | c.3140C>T p.S1047L (on ENST00000377086 / NM_001365952.1; = p.S1001L on NM_015074.3) | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs267597898, COSV55811951; called by muse, mutect2, varscan2
- KIF20A | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 32/267 reads (12%) | catalogued as rs779440603; called by muse, mutect2, varscan2
- KIF2A | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs777382535, COSV66945840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF5B | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 88/536 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs377656602; called by muse, mutect2, varscan2
- KLF16 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.354); catalogued as rs1440491671; called by muse, mutect2
- KLRG2 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1218084165, COSV61800901; called by muse, mutect2, varscan2
- L3MBTL1 | c.2236C>T p.R746C (on ENST00000418998 / NM_001377303.1; = p.R656C on NM_015478.7) | Missense Mutation (SNP) | VAF 48/312 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144951279; called by muse, mutect2, varscan2
- LGALS13 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 29/289 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1303608067, COSV99695050; called by muse, mutect2, varscan2
- LGI2 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767382221, COSV66123864; called by muse, mutect2, varscan2
- LHX9 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 72/500 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1308471113; called by muse, mutect2, varscan2
- LLGL1 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as rs759554948; called by muse, mutect2, varscan2
- LMF2 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as rs558923692; called by muse, varscan2
- LMX1A | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs749385148, COSV99673081; called by muse, mutect2, varscan2
- LONP1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99052281; called by muse, mutect2, varscan2
- LPCAT4 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs776501231; called by muse, mutect2, varscan2
- LRBA | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371936024; called by muse, mutect2, varscan2
- LRIG1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs373112316; called by muse, mutect2, varscan2
- LRP1 | c.6964C>T p.R2322C | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1403053376; called by muse, mutect2, varscan2
- LRRC4B | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV65349201; called by muse, mutect2, varscan2
- LRRFIP1 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 104/513 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs375809493; called by muse, mutect2, varscan2
- LRRK2 | c.4429C>T p.R1477* | Nonsense Mutation (SNP) | VAF 20/665 reads (3%) | catalogued as rs1010617973, COSV100110135; called by muse, mutect2
- LTN1 | c.3295C>T p.R1099* | Nonsense Mutation (SNP) | VAF 18/507 reads (4%) | catalogued as rs866219851; called by muse, mutect2
- LY6G6F-LY6G6D | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 76/484 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs908403443, COSV65442557; called by muse, mutect2
- MAGEB16 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 81/473 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs774566572, COSV104433685; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 22/137 reads (16%) | catalogued as rs1215313075; called by mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 17/127 reads (13%) | catalogued as rs762648935; called by mutect2, varscan2
- MBTD1 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 76/490 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs747834993; called by muse, mutect2, varscan2
- MCC | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.898); catalogued as rs537132002; called by muse, mutect2, varscan2
- MCM2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as rs200231306, COSV54031921; called by muse, varscan2
- MDN1 | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 74/434 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773314424; called by muse, mutect2, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 19/180 reads (11%) | catalogued as rs759225724; called by mutect2, varscan2
- MET | c.1483A>G p.T495A | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.048); catalogued as COSV59259596; called by muse, mutect2, varscan2
- MGAM | c.2167C>A p.L723I | Missense Mutation (SNP) | VAF 28/560 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV72075778; called by muse, mutect2
- MICAL1 | c.1869G>T p.Q623H | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as rs1195970533; called by muse, mutect2
- MOB2 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777745822; called by muse, mutect2, varscan2
- MPL | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200454070, COSV99055374; called by muse, mutect2
- MPST | c.808C>G p.P270A (on ENST00000341116 / NM_001369904.2; = p.P290A on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174078099; called by muse, mutect2, varscan2
- MPV17L2 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55852242; called by muse, mutect2
- MRC2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765734147; called by muse, mutect2, varscan2
- MRPL4 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1215912278, COSV53449697; called by muse, mutect2
- MSH4 | c.2728C>T p.R910* | Nonsense Mutation (SNP) | VAF 78/550 reads (14%) | catalogued as rs771456188, COSV99592878; called by muse, mutect2, varscan2
- MTCH2 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as rs77581661, COSV56766844; called by muse, mutect2, varscan2
- MUC12 | c.1823C>T p.S608L (on ENST00000379442; = p.S465L on NM_001164462.1) | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.316); catalogued as rs12533349, COSV65199517; called by muse, mutect2
- MUC16 | c.40646C>T p.A13549V | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.847); catalogued as COSV101109820; called by muse, mutect2, varscan2
- MYBPC1 | c.2882C>T p.A961V (on ENST00000550270 / NM_206820.2; = p.A968V on NM_002465.4) | Missense Mutation (SNP) | VAF 79/414 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs755894383; called by muse, mutect2, varscan2
- MYMK | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs770599578; called by muse, mutect2, varscan2
- MYO1A | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369452147; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MYORG | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs1469373049; called by muse, mutect2, varscan2
- NAA60 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1374516163; called by muse, mutect2, varscan2
- NBEAL2 | c.6007C>T p.P2003S | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52754366; called by muse, mutect2, varscan2
- NCAM1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.435); catalogued as rs185400485, COSV57519243; called by muse, mutect2
- NCKIPSD | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs371383008; called by muse, mutect2, varscan2
- NCKIPSD | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs376825176; called by muse, mutect2, varscan2
- NCOA2 | c.3956C>T p.T1319M | Missense Mutation (SNP) | VAF 54/321 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as rs774257324, COSV51219736; called by muse, mutect2, varscan2
- NCOR2 | c.3178dup p.R1060Pfs*2 | Frame Shift Ins (INS) | VAF 34/241 reads (14%) | catalogued as rs749518211; called by mutect2, varscan2
- NDRG1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 49/355 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as rs777244818; called by muse, mutect2, varscan2
- NDRG4 | c.310G>A p.G104R (on ENST00000570248 / NM_001378344.1; = p.G136R on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs369106170, COSV50746448, COSV99059954; called by muse, mutect2, varscan2
- NDUFA9 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201865179; called by muse, mutect2, varscan2
- NECTIN1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs371158952, COSV50598077; called by muse, mutect2, varscan2
- NELFE | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 18/596 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs754439377, COSV100952920; called by muse, mutect2
- NFATC1 | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs139882199; called by muse, mutect2, varscan2
- NFATC2IP | c.787del p.R263Dfs*60 | Frame Shift Del (DEL) | VAF 26/188 reads (14%) | catalogued as rs765645344; called by mutect2, varscan2
- NLRP6 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs1379500532; called by muse, varscan2
- NOC4L | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1469735325; called by muse, mutect2
- NOL12 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs141277853; called by muse, mutect2
- NOTCH1 | c.5189C>T p.P1730L | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs375897519; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.1415G>A p.G472E | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53033055, COSV53039134; called by muse, mutect2
- NPAP1 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61507839; called by muse, mutect2, varscan2
- NPHS1 | c.2597G>A p.R866Q | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.218); catalogued as rs868576714; called by muse, mutect2, varscan2
- NPR1 | c.1818dup p.N607Qfs*21 | Frame Shift Ins (INS) | VAF 31/182 reads (17%) | catalogued as rs772189906; called by mutect2, varscan2
- NR2C2 | c.322G>A p.V108I (on ENST00000393102; = p.V127I on NM_003298.5) | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as rs762221262, COSV60146632; called by muse, mutect2, varscan2
- NRG1 | c.245del p.P82Lfs*26 (on ENST00000523534; = p.P229Lfs*26 on NM_013962.2) | Frame Shift Del (DEL) | VAF 24/164 reads (15%) | catalogued as COSV73059882; called by mutect2, varscan2
- NRXN2 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs769291803, COSV55447013; called by muse, mutect2, varscan2
- NSD3 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1250796714, COSV57619196; called by muse, mutect2, varscan2
- NSMAF | c.2131A>G p.M711V | Missense Mutation (SNP) | VAF 89/554 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as rs529100436; called by muse, mutect2, varscan2
- NTRK1 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 23/297 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.269); catalogued as COSV62328403; called by muse, mutect2
- NUDT18 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776397436, COSV57158831; called by muse, mutect2, varscan2
- NUP210L | c.3367G>A p.V1123M | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746145392, COSV99666932; called by muse, mutect2, varscan2
- OBSL1 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767009179, COSV54718742; called by muse, mutect2, varscan2
- OLFML1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 79/480 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.369); catalogued as rs774002516, COSV61401793; called by muse, mutect2, varscan2
- OLFML2B | c.1783G>A p.V595M | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780805933, COSV54200720; called by muse, mutect2, varscan2
- OPA1 | c.2818C>T p.R940C (on ENST00000361510 / NM_130837.3; = p.R885C on NM_015560.3) | Missense Mutation (SNP) | VAF 101/492 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs927450242; called by muse, varscan2
- OR10J3 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.542); catalogued as rs1395137790; called by muse, mutect2, varscan2
- OR12D2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 160/779 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs765400893; called by muse, mutect2, varscan2
- OR1C1 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 113/475 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs376185600; called by muse, mutect2, varscan2
- OR4C11 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 77/466 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs1446936576; called by muse, mutect2, varscan2
- OR4P4 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770410713; called by muse, mutect2, varscan2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 62/301 reads (21%) | catalogued as rs780916980; called by mutect2, varscan2
- OSBPL2 | c.1113del p.N372Tfs*13 (on ENST00000313733 / NM_144498.4; = p.N360Tfs*13 on NM_014835.4) | Frame Shift Del (DEL) | VAF 25/134 reads (19%) | catalogued as COSV58215176; called by mutect2, varscan2
- P4HA1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 80/513 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1024039064; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1114C>T p.R372C (on ENST00000374531 / NM_001037293.2; = p.R404C on NM_053016.6) | Missense Mutation (SNP) | VAF 27/257 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs535977013, COSV57117854; called by muse, mutect2, varscan2
- PAX7 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV100946958; called by muse, mutect2, varscan2
- PCDHA1 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV100974626, COSV65375514; called by muse, mutect2
- PCDHB1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1554267053; called by muse, mutect2, varscan2
- PCDHB3 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.244); catalogued as rs782146000, COSV50608941; called by muse, varscan2
- PCDHGB1 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781547082, COSV53976716; called by muse, mutect2, varscan2
- PCDHGB6 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV53946573; called by muse, mutect2, varscan2
- PCP4 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV60787097; called by muse, mutect2, varscan2
- PDE1B | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324446563, COSV54496889; called by muse, mutect2, varscan2
- PGAM2 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs374395743; called by muse, mutect2, varscan2
- PHOX2B | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs1242397056; ClinVar: uncertain significance; called by muse, mutect2
- PHRF1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1398196971, COSV99213401; called by muse, mutect2
- PI16 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65448100; called by muse, mutect2, varscan2
- PIGQ | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs751055581; called by muse, mutect2, varscan2
- PIK3C2A | c.4339C>T p.R1447* | Nonsense Mutation (SNP) | VAF 40/238 reads (17%) | catalogued as rs747073851, COSV56405609; called by muse, mutect2, varscan2
- PKD1 | c.12779G>A p.R4260H (on ENST00000262304 / NM_001009944.3; = p.R4259H on NM_000296.4) | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs750700500; called by muse, mutect2, varscan2
- PKP2 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 69/304 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs543281875, COSV50726677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAC8L1 | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 68/391 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs776737291, COSV61013573; called by muse, mutect2, varscan2
- PLCE1 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 72/424 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as rs1482772158, COSV53357049; called by muse, mutect2, varscan2
- PLD1 | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100577663, COSV60565858; called by muse, mutect2, varscan2
- PLEC | c.12337G>A p.V4113I (on ENST00000322810 / NM_201380.4; = p.V4003I on NM_000445.5) | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as rs782422260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.5471G>A p.R1824Q (on ENST00000322810 / NM_201380.4; = p.R1714Q on NM_000445.5) | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs563046387; called by muse, mutect2, varscan2
- PLEKHB2 | c.538T>C p.Y180H (on ENST00000409279; = p.Y179H on NM_017958.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV52178392; called by muse, mutect2
- PLXNB1 | c.536del p.G179Vfs*41 | Frame Shift Del (DEL) | VAF 30/188 reads (16%) | catalogued as rs953293505; called by mutect2, varscan2
- PLXNB2 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs531070913, COSV63783054; called by muse, mutect2, varscan2
- PNPLA2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs773938209; called by muse, mutect2, varscan2
- PNPLA8 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 55/468 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.026); catalogued as rs1261274636; called by muse, mutect2, varscan2
- POGZ | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs748955181; called by muse, varscan2
- POLR3E | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1463897933; called by muse, varscan2
- POTEC | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100743265, COSV100743946; called by muse, mutect2, varscan2
- PPM1D | c.1349dup p.L450Ffs*6 | Frame Shift Ins (INS) | VAF 64/360 reads (18%) | catalogued as rs758630849; called by mutect2, varscan2
- PPP1R26 | c.2692del p.V898Sfs*56 | Frame Shift Del (DEL) | VAF 26/166 reads (16%) | catalogued as rs1365223299; called by mutect2, varscan2
- PPP3R2 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs746497872, COSV62452747; called by muse, mutect2
- PRDM16 | c.2057C>T p.T686M | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs868332674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCD | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57851416; called by muse, mutect2, varscan2
- PRKD3 | c.2020C>T p.R674* | Nonsense Mutation (SNP) | VAF 45/390 reads (12%) | catalogued as rs1404288610; called by muse, mutect2, varscan2
- PRPSAP1 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61211222; called by muse, mutect2, varscan2
- PRR12 | c.37del p.H13Tfs*66 (on ENST00000615927; = p.P408Hfs*62 on NM_020719.3) | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | catalogued as rs763575972; called by mutect2, varscan2
- PRRC2C | c.1711C>T p.R571W (on ENST00000367742; = p.R569W on NM_015172.4) | Missense Mutation (SNP) | VAF 58/540 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs373214431; called by muse, mutect2, varscan2
- PRX | c.3091C>T p.R1031W | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1399950077, COSV99397952; called by muse, mutect2, varscan2
- PSG3 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as rs368098899; called by muse, mutect2
- PTPRK | c.4192C>T p.R1398W (on ENST00000368215 / NM_001291984.2; = p.R1399W on NM_002844.4) | Missense Mutation (SNP) | VAF 87/565 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs370374055; called by muse, mutect2, varscan2
- PTPRN | c.92del p.G31Afs*75 | Frame Shift Del (DEL) | VAF 24/121 reads (20%) | catalogued as rs1179811215; called by mutect2, varscan2
- PWWP2A | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 42/371 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1199611967; called by muse, mutect2, varscan2
- QSOX1 | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs758947386, COSV100852971; called by muse, mutect2, varscan2
- R3HDM2 | c.1469A>G p.N490S | Missense Mutation (SNP) | VAF 22/393 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1043617722; called by muse, mutect2
- RAB13 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63945244; called by muse, mutect2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 58/312 reads (19%) | catalogued as rs745353960; called by mutect2, varscan2
- RAI1 | c.4666C>T p.R1556C | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs925201797, COSV99883694; called by muse, mutect2
- RASGEF1A | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs767084570, COSV65666676; called by muse, mutect2, varscan2
- RASIP1 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1372516730; called by muse, mutect2, varscan2
- RBFA | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs372074483; called by muse, mutect2, varscan2
- RBM24 | c.695C>T p.T232I (on ENST00000379052 / NM_001143942.2; = p.T187I on NM_153020.2) | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV59003632; called by muse, mutect2
- RBM33 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 69/401 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as rs761329600; called by muse, mutect2, varscan2
- RBPJL | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767768517, COSV59214043; called by muse, mutect2, varscan2
- RECK | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 58/337 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs373443775; called by muse, mutect2, varscan2
- RFC5 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200087929, COSV57478554; called by muse, mutect2, varscan2
- RHBDF1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1420716224, COSV51954242, COSV51954596; called by muse, mutect2
- RHOXF2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs781886657, COSV65047714, COSV65048009; called by muse, mutect2, varscan2
- RNF40 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.022); catalogued as rs186930335; called by muse, mutect2, varscan2
- RNF40 | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753414503, COSV61215442; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 80/255 reads (31%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROBO4 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs777716177; called by muse, mutect2, varscan2
- RPS26 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs764673368; called by muse, mutect2, varscan2
- RRNAD1 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs761902145; called by muse, mutect2, varscan2
- RYBP | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV72180442; called by muse, mutect2
- SBF1 | c.3394C>T p.R1132C | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375823291; called by muse, mutect2, varscan2
- SBF1 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763212089, COSV62368870; called by muse, mutect2, varscan2
- SBNO2 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.568); catalogued as rs368375543, COSV62320156; called by muse, mutect2, varscan2
- SBSN | c.915del p.Q306Rfs*134 | Frame Shift Del (DEL) | VAF 34/258 reads (13%) | catalogued as COSV71733302; called by mutect2, varscan2
- SCAF1 | c.1034A>G p.D345G | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs1190076794; called by muse, mutect2, varscan2
- SCART1 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62986246; called by muse, mutect2, varscan2
- SCN3A | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 65/548 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1229817884; called by muse, varscan2
- SCP2 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65261377; called by mutect2, varscan2
- SCUBE2 | c.1825C>T p.R609* | Nonsense Mutation (SNP) | VAF 28/218 reads (13%) | catalogued as rs778614754, COSV58544121; called by muse, mutect2, varscan2
- SEC23IP | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 96/527 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs370450206; called by muse, mutect2, varscan2
- SEC24B | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs762396474, COSV54506724; called by muse, mutect2, varscan2
- SEC31A | c.3184C>T p.P1062S (on ENST00000355196 / NM_001318120.1; = p.P1023S on NM_016211.4) | Missense Mutation (SNP) | VAF 27/578 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV52341722; called by muse, mutect2
- SELL | c.251C>T p.A84V (on ENST00000650983; = p.A71V on NM_000655.5) | Missense Mutation (SNP) | VAF 58/515 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1347222080, COSV52551637; called by muse, mutect2, varscan2
- SEMA5A | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs144473454; called by muse, mutect2, varscan2
- SEPTIN4 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 30/257 reads (12%) | catalogued as rs199652012; called by muse, mutect2, varscan2
- SEPTIN8 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs371690570; called by muse, mutect2, varscan2
- SGO1 | c.1564dup p.R522Kfs*29 (on ENST00000263753 / NM_001012410.5; = p.R253Kfs*29 on NM_138484.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 32/203 reads (16%) | catalogued as rs772386209; called by mutect2, varscan2
- SHLD1 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368912927; called by muse, mutect2, varscan2
- SIPA1L3 | c.4081C>T p.R1361W | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs374780684; called by muse, mutect2, varscan2
- SIRPA | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100605219; called by muse, mutect2, varscan2
- SIRPA | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 30/227 reads (13%) | catalogued as rs765828306; called by muse, mutect2, varscan2
- SIRT2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs756288624; called by muse, mutect2, varscan2
- SLC12A7 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1380345284; called by muse, varscan2
- SLC22A2 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 53/243 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.164); catalogued as rs771745592, COSV65266251; called by muse, mutect2, varscan2
- SLC25A47 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); catalogued as rs140446618; called by muse, mutect2, varscan2
- SLC27A1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886598213, COSV53100742; called by muse, mutect2, varscan2
- SLC35B2 | c.1291_1293del p.K431del | In Frame Del (DEL) | VAF 22/168 reads (13%) | catalogued as rs752392556; called by mutect2, varscan2
- SLC48A1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50410589; called by muse, mutect2, varscan2
- SLC52A1 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.433); catalogued as rs150164483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A9 | c.973G>A p.V325M (on ENST00000360584 / NM_201649.4; = p.V271M on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs200759556, COSV100746527, COSV100746583; called by muse, mutect2, varscan2
- SLF2 | c.2713A>T p.I905F | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53275583; called by muse, mutect2
- SMCO4 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs140592708, COSV100127888, COSV54360616; called by muse, mutect2
- SMIM24 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs868388883; called by muse, mutect2, varscan2
- SMURF1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1445831623; called by muse, mutect2, varscan2
- SNAPC4 | c.4097C>T p.A1366V | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as rs752050888, COSV53737813; called by muse, mutect2, varscan2
- SNRNP200 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs759448209, COSV60488738; called by muse, mutect2
- SNRNP25 | c.160C>T p.P54S (on ENST00000383018; = p.P45S on NM_024571.4) | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as rs762660007, COSV51957790; called by muse, mutect2, varscan2
- SNX11 | c.327-1G>T p.X109_splice | Splice Site (SNP) | VAF 12/182 reads (7%) | catalogued as COSV63658520; called by muse, mutect2
- SNX20 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs775632741, COSV100319084; called by muse, mutect2, varscan2
- SOCS2 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 32/648 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as rs1338679125; called by muse, mutect2
- SPATA2 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746233167, COSV56866665; called by muse, mutect2, varscan2
- SPEN | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 68/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752192287; called by muse, mutect2, varscan2
- SPOUT1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs756502359, COSV63509214; called by muse, mutect2, varscan2
- SPTY2D1 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 105/612 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768279652; called by muse, mutect2, varscan2
- SRSF5 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 66/431 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs191376708; called by muse, mutect2, varscan2
- SSBP1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 74/472 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); catalogued as rs148271472; called by muse, varscan2
- SSH2 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 73/450 reads (16%) | catalogued as rs1171387969; called by muse, mutect2, varscan2
- STK10 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs766953268; called by muse, mutect2, varscan2
- STOML1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 57/307 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs776788505; called by muse, mutect2, varscan2
- STRIP1 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs146229969; called by muse, varscan2
- STRN3 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 22/421 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.247); catalogued as rs1484554988; called by muse, mutect2
- SUMO2 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as rs1204753119, COSV58813600; called by muse, mutect2, varscan2
- SYTL3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1270112786; called by muse, mutect2
- TAF1 | c.2468G>A p.R823Q (on ENST00000373790 / NM_138923.4; = p.R844Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/441 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52115163; called by muse, mutect2
- TAF11L2 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1160403496; called by muse, varscan2
- TAF1C | c.1361del p.P454Lfs*14 | Frame Shift Del (DEL) | VAF 32/162 reads (20%) | catalogued as rs749363736; called by mutect2, varscan2
- TAF2 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs773854593, COSV65418415; called by muse, mutect2, varscan2
- TAS1R1 | c.2453G>A p.R818H | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1349457816; called by muse, varscan2
- TBC1D13 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1429757800; called by mutect2, varscan2
- TBL3 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60340596; called by muse, mutect2, varscan2
- TCAP | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs779699520, COSV54094388; called by muse, mutect2, varscan2
- TDRD5 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.233); catalogued as rs779368895, COSV99677539; called by muse, mutect2, varscan2
- TEAD2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs556204126, COSV60545238; called by muse, mutect2, varscan2
- TEDC2 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs759305264, COSV62522828; called by muse, mutect2, varscan2
- TENM2 | c.7694C>T p.T2565M (on ENST00000518659 / NM_001122679.2; = p.T2326M on NM_001080428.3) | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs374088936; called by muse, mutect2, varscan2
- TEX45 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV64463445, COSV64464194; called by muse, mutect2
- TJP1 | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 62/491 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1288621536; called by muse, mutect2, varscan2
- TLE6 | c.1330C>T p.R444W (on ENST00000246112 / NM_001143986.2; = p.R321W on NM_024760.3) | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751705597, COSV55735559; called by muse, mutect2, varscan2
- TMC7 | c.2114G>A p.R705H | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1220471909; called by muse, mutect2, varscan2
- TMEM19 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 78/405 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs778761272, COSV56999712; called by muse, mutect2, varscan2
- TMEM201 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746336377; called by muse, mutect2, varscan2
- TMPRSS12 | c.795+7C>T | Splice Region (SNP) | VAF 50/347 reads (14%) | catalogued as rs777612545; called by muse, mutect2, varscan2
- TNC | c.5708C>T p.A1903V | Missense Mutation (SNP) | VAF 23/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1220118170, COSV100404776, COSV60792530; called by muse, mutect2
- TNFRSF11A | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as rs757983626, COSV54025565; called by muse, varscan2
- TNFRSF8 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141023619; called by muse, mutect2, varscan2
- TNS1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 68/342 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762043344, COSV50698478; called by muse, mutect2, varscan2
- TPCN2 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs770687181, COSV99037211; called by muse, mutect2, varscan2
- TRIM47 | c.1699G>A p.G567S | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.442); catalogued as rs748329899, COSV99638512; called by muse, mutect2, varscan2
- TRIP10 | c.995del p.P332Hfs*31 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs1173371682; called by mutect2, varscan2
- TRPC3 | c.2032G>A p.A678T (on ENST00000379645 / NM_001366479.2; = p.A605T on NM_003305.2) | Missense Mutation (SNP) | VAF 33/325 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs1446275099; called by muse, mutect2, varscan2
- TRPC5 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV53287159; called by muse, mutect2
- TRRAP | c.2698G>A p.G900S | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62847716; called by muse, mutect2
- TRRAP | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62841933; called by muse, varscan2
- TTC22 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.899); catalogued as rs1162291546; called by muse, mutect2, varscan2
- TTC7A | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758259662, COSV55408475; called by mutect2, varscan2
- TTLL3 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs540565542, COSV59613688; called by muse, mutect2, varscan2
- TTN | c.81010G>A p.A27004T (on ENST00000591111; = p.A19580T on NM_003319.4) | Missense Mutation (SNP) | VAF 18/448 reads (4%) | PolyPhen probably damaging (0.998); catalogued as rs879226652; called by muse, mutect2
- TTN | c.40313T>C p.L13438P (on ENST00000591111; = p.L6014P on NM_003319.4) | Missense Mutation (SNP) | VAF 128/632 reads (20%) | PolyPhen benign (0.186); catalogued as rs1033335592, COSV59976479; called by muse, mutect2, varscan2
- TTN | c.21048G>T p.E7016D (on ENST00000591111; = p.E6089D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/442 reads (18%) | PolyPhen benign (0.012); catalogued as COSV100628744; called by muse, mutect2
- TUBB4A | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.043); catalogued as COSV51160341; called by muse, varscan2
- TXNDC2 | c.530G>A p.G177D (on ENST00000306084 / NM_001098529.2; = p.G110D on NM_032243.6) | Missense Mutation (SNP) | VAF 71/439 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV60153537; called by muse, mutect2, varscan2
- UBA7 | c.2627G>A p.R876Q | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs199939644; called by muse, mutect2
- UBAP1L | c.739dup p.A247Gfs*13 | Frame Shift Ins (INS) | VAF 26/224 reads (12%) | catalogued as rs753661357; called by mutect2, varscan2
- UBE2S | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1369706768, COSV99198773; called by muse, mutect2
- UBXN2B | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 78/423 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345383179, COSV68308890; called by muse, mutect2, varscan2
- UNC45A | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs373214423; called by muse, mutect2, varscan2
- UNC5B | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372528064; called by mutect2, varscan2
- USH2A | c.98C>A p.S33* | Nonsense Mutation (SNP) | VAF 16/504 reads (3%) | catalogued as COSV100232365; called by muse, mutect2
- UTP4 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 25/304 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs762272300, COSV58732102; called by muse, mutect2
- UVSSA | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs1232484194, COSV66230616; called by muse, mutect2, varscan2
- UXS1 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs768079305; called by muse, varscan2
- VANGL1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 72/358 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs752742934, CM127310; called by muse, varscan2
- WFIKKN2 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.028); catalogued as rs375510528; called by muse, mutect2
- WNK2 | c.6341G>A p.R2114H (on ENST00000297954 / NM_001282394.1; = p.R2077H on NM_006648.3) | Missense Mutation (SNP) | VAF 47/246 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1388947041; called by muse, mutect2, varscan2
- WNT9B | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs765555952, COSV99255014; called by muse, mutect2, varscan2
- XIRP1 | c.3971C>T p.P1324L | Missense Mutation (SNP) | VAF 75/362 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769089308, COSV61137375; called by muse, mutect2, varscan2
- YIPF4 | c.56T>C p.F19S | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.207); catalogued as rs1350733551; called by muse, mutect2
- ZACN | c.756del p.L253Cfs*10 | Frame Shift Del (DEL) | VAF 44/246 reads (18%) | catalogued as rs746294699; called by mutect2, varscan2
- ZAN | c.5890G>A p.A1964T | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs771814609; called by muse, mutect2, varscan2
- ZBTB37 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62932340; called by muse, mutect2
- ZBTB44 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1028585105, COSV63537729; called by muse, varscan2
- ZBTB8B | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 36/210 reads (17%) | catalogued as rs766409585; called by muse, mutect2, varscan2
- ZEB1 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 78/483 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs754135071, COSV58042268, COSV58050747; called by muse, mutect2, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 44/242 reads (18%) | catalogued as rs762108866; called by mutect2, varscan2
- ZFP92 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1556975095; called by muse, varscan2
- ZNF219 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs1290601756; called by muse, mutect2, varscan2
- ZNF224 | c.1100C>T p.T367M | Missense Mutation (SNP) | VAF 89/456 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs763968126; called by muse, mutect2
- ZNF236 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 61/317 reads (19%) | catalogued as rs1191784802; called by muse, mutect2, varscan2
- ZNF518A | c.57del p.D20Ifs*4 | Frame Shift Del (DEL) | VAF 40/282 reads (14%) | catalogued as COSV60151560; called by mutect2, varscan2
- ZNF521 | c.2684A>G p.Y895C | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64130931; called by muse, mutect2, varscan2
- ZNF524 | c.214del p.V72* | Frame Shift Del (DEL) | VAF 52/242 reads (21%) | catalogued as rs1249713061; called by mutect2, varscan2
- ZNF574 | c.418C>A p.L140I | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs759453967; called by muse, mutect2, varscan2
- ZNF626 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV99391808; called by muse, mutect2, varscan2
- ZNF728 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs530488414, COSV74099329; called by muse, mutect2, varscan2
- ZNF750 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV53958190; called by muse, mutect2
- ZNF775 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1241882894; called by muse, mutect2, varscan2
- ABCB9 | c.1682del p.G561Afs*21 (on ENST00000280560 / NM_019625.4; = p.G518Afs*21 on NM_019624.3) | Frame Shift Del (DEL) | VAF 50/210 reads (24%) | called by mutect2, varscan2
- ABCC8 | c.3065dup p.H1023Afs*91 | Frame Shift Ins (INS) | VAF 37/188 reads (20%) | called by mutect2, varscan2
- AC006059.2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 48/270 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- AC090517.4 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 25/402 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2
- ACACA | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACLY | c.1354A>G p.R452G | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); called by muse, varscan2
- ADA | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, varscan2
- ADAM20 | c.2117del p.L706Yfs*? | Frame Shift Del (DEL) | VAF 48/328 reads (15%) | called by mutect2, varscan2
- ADAMTS1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2
- ADCY5 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2
- ADCY7 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ADGRG2 | c.860C>A p.P287H (on ENST00000379869 / NM_001079858.3; = p.P284H on NM_005756.4) | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); called by muse, mutect2
- AGRN | c.5233del p.R1745Vfs*15 | Frame Shift Del (DEL) | VAF 21/119 reads (18%) | called by mutect2, varscan2
- AGTPBP1 | c.1277del p.F426Sfs*13 (on ENST00000357081 / NM_001330701.2; = p.F386Sfs*13 on NM_015239.2) | Frame Shift Del (DEL) | VAF 48/332 reads (14%) | called by mutect2, varscan2
- AHNAK | c.13635G>T p.E4545D | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AIP | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AKNA | c.3969del p.G1324Dfs*72 | Frame Shift Del (DEL) | VAF 45/314 reads (14%) | called by mutect2, varscan2
- ALOX12B | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- ANO8 | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.168); called by muse, mutect2
- APP | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- ARAF | c.23del p.P8Lfs*26 | Frame Shift Del (DEL) | VAF 50/236 reads (21%) | called by mutect2, varscan2
- ARHGEF1 | c.1030del p.L344Wfs*12 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by mutect2, varscan2
- ARID5B | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 70/470 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMC10 | c.787T>C p.S263P | Missense Mutation (SNP) | VAF 23/460 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ASAP3 | c.2578dup p.A860Gfs*5 | Frame Shift Ins (INS) | VAF 22/192 reads (11%) | called by mutect2, varscan2
- ASCC3 | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ASTN2 | c.2365A>G p.N789D (on ENST00000313400 / NM_001365069.1; = p.N738D on NM_014010.5) | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- ATF2 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2
- ATG2B | c.4973A>G p.Q1658R | Missense Mutation (SNP) | VAF 84/545 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ATP1A3 | c.1998C>A p.C666* (on ENST00000545399 / NM_001256214.2; = p.C653* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- ATP2A1 | c.1941G>T p.E647D | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP6V1B2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 58/394 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); called by muse, varscan2
- ATXN1 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ATXN7L2 | c.1995G>T p.E665D | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- B4GALNT4 | c.1240del p.D414Mfs*81 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, varscan2
- BAHCC1 | c.7414C>T p.P2472S | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- BARD1 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 42/698 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.871); called by muse, mutect2
- BIRC2 | c.134G>A p.C45Y | Missense Mutation (SNP) | VAF 69/462 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BRCA2 | c.9333G>T p.E3111D | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BRD3 | c.449del p.P150Lfs*93 | Frame Shift Del (DEL) | VAF 30/202 reads (15%) | called by mutect2, varscan2
- BRPF3 | c.3241T>C p.W1081R | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRWD1 | c.6657A>T p.E2219D | Missense Mutation (SNP) | VAF 24/724 reads (3%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- BTNL9 | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2
- C3orf52 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 24/427 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); called by muse, mutect2
- C6orf132 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- CAD | c.3718C>T p.R1240W | Missense Mutation (SNP) | VAF 61/317 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- CADM2 | c.464C>T p.A155V (on ENST00000407528 / NM_001167674.2; = p.A157V on NM_153184.4) | Missense Mutation (SNP) | VAF 55/476 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMK2A | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMK2G | c.1388A>G p.E463G (on ENST00000423381 / NM_001367518.1; = p.E400G on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CAPN12 | c.1217del p.G406Afs*33 | Frame Shift Del (DEL) | VAF 26/122 reads (21%) | called by mutect2, varscan2
- CAPZB | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 24/435 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); called by muse, mutect2
- CARD9 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); called by muse, varscan2
- CASS4 | c.1764del p.F588Lfs*13 | Frame Shift Del (DEL) | VAF 34/230 reads (15%) | called by mutect2, varscan2
- CCDC3 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 24/188 reads (13%) | called by muse, varscan2
- CDH10 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 24/781 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- CDH23 | c.3953A>G p.Y1318C | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CDHR1 | c.2236C>A p.P746T | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CDKL5 | c.2786C>T p.T929I | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- CFAP54 | c.7931del p.N2644Mfs*7 | Frame Shift Del (DEL) | VAF 36/244 reads (15%) | called by mutect2, varscan2
- CHP2 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CIC | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLIC3 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLPB | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNNM2 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- CNOT3 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CNTN5 | c.2914T>A p.S972T | Missense Mutation (SNP) | VAF 31/404 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2
- COBL | c.2102T>G p.L701R | Missense Mutation (SNP) | VAF 25/469 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); called by muse, mutect2
- COG5 | c.494del p.G165Efs*5 | Frame Shift Del (DEL) | VAF 65/358 reads (18%) | called by mutect2, varscan2
- COL13A1 | c.2033G>T p.R678M (on ENST00000398978 / NM_001130103.2; = p.R606M on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL6A5 | c.1031T>G p.L344R | Missense Mutation (SNP) | VAF 64/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COX18 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRACR2A | c.1268G>T p.R423M | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- CRISP3 | c.802T>C p.S268P (on ENST00000371159 / NM_001368123.1; = p.S250P on NM_006061.4) | Missense Mutation (SNP) | VAF 32/567 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- CSPP1 | c.3314A>G p.D1105G (on ENST00000676605; = p.D1064G on NM_024790.6) | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, varscan2
- CTAGE6 | c.794A>G p.H265R | Missense Mutation (SNP) | VAF 42/812 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- CTNND2 | c.3166A>G p.T1056A | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CUL2 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 35/273 reads (13%) | called by muse, mutect2, varscan2
- CUL3 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 50/261 reads (19%) | called by muse, mutect2, varscan2
- DENND3 | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 74/498 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- DENND4A | c.1664T>C p.L555S | Missense Mutation (SNP) | VAF 67/497 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DIP2C | c.3107del p.P1036Qfs*3 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | called by mutect2, varscan2
- DIP2C | c.1009C>A p.L337M | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- DNAH5 | c.2300C>A p.P767H | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2
- DNMT3B | c.1787T>C p.I596T | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.7763_7764dup p.D2589Mfs*21 | Frame Shift Ins (INS) | VAF 35/256 reads (14%) | called by mutect2, varscan2
- DUSP2 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2
- DUSP6 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 137/600 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DYM | c.1262del p.N421Ifs*10 | Frame Shift Del (DEL) | VAF 36/210 reads (17%) | called by mutect2, varscan2
- DYNC1LI2 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by mutect2, varscan2
- DYNC2I1 | c.2777dup p.L926Ffs*85 | Frame Shift Ins (INS) | VAF 32/174 reads (18%) | called by mutect2, varscan2
- E4F1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 42/215 reads (20%) | called by muse, mutect2, varscan2
- EBF1 | c.1714T>C p.C572R | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- EBF4 | c.768del p.C257Afs*63 (on ENST00000609451; = p.C253Afs*63 on NM_001110514.1) | Frame Shift Del (DEL) | VAF 15/125 reads (12%) | called by mutect2, varscan2
- ECRG4 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- EED | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 42/298 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1825G>T p.G609C (on ENST00000361735 / NM_015935.5; = p.G523C on NM_014955.3) | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EI24 | c.199A>G p.I67V | Missense Mutation (SNP) | VAF 20/501 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- EIF3J | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- EIF4G3 | c.4097A>G p.Q1366R | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EML5 | c.5722G>A p.D1908N (on ENST00000380664; = p.D1916N on NM_183387.3) | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENPP5 | c.973C>T p.H325Y | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERC2 | c.2354A>G p.E785G | Missense Mutation (SNP) | VAF 27/659 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- FASN | c.3358A>G p.T1120A | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FBXL17 | c.2098T>G p.S700A | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2
- FEZF1 | c.721dup p.I241Nfs*14 | Frame Shift Ins (INS) | VAF 54/298 reads (18%) | called by mutect2, varscan2
- FLT4 | c.692A>T p.D231V | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- FNBP1 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 31/381 reads (8%) | called by muse, mutect2
- FRAS1 | c.3916C>T p.Q1306* | Nonsense Mutation (SNP) | VAF 40/286 reads (14%) | called by muse, mutect2, varscan2
- FRAS1 | c.5735del p.N1912Tfs*24 | Frame Shift Del (DEL) | VAF 66/461 reads (14%) | called by mutect2, varscan2
- FRMPD3 | c.339A>G p.I113M | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FSCN1 | c.303G>A p.W101* | Nonsense Mutation (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- FSIP2 | c.10006A>G p.T3336A | Missense Mutation (SNP) | VAF 26/632 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- FUT9 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 84/589 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FZD4 | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATAD2B | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 52/398 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, varscan2
- GCC2 | c.1995del p.K665Nfs*2 | Frame Shift Del (DEL) | VAF 65/356 reads (18%) | called by mutect2, varscan2
- GDF10 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNA12 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA8K | c.932T>C p.L311P | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPD1 | c.364dup p.X122_splice | Splice Site (INS) | VAF 14/112 reads (13%) | called by mutect2, varscan2
- GPR148 | c.490dup p.A164Gfs*130 | Frame Shift Ins (INS) | VAF 28/246 reads (11%) | called by mutect2, varscan2
- GRK7 | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GTF2F1 | c.536A>G p.Q179R | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- H2BC7 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 83/436 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- HCFC1 | c.2216C>T p.T739M | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- HERC1 | c.10560A>C p.L3520F | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- HERC2 | c.8650T>C p.Y2884H | Missense Mutation (SNP) | VAF 14/319 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- HIC2 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- HMGXB4 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 60/563 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- IGLV3-12 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2
- IL5RA | c.656G>A p.S219N | Missense Mutation (SNP) | VAF 25/425 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- INO80D | c.1914del p.F638Lfs*25 | Frame Shift Del (DEL) | VAF 43/206 reads (21%) | called by mutect2, varscan2
- INSR | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INTS13 | c.2111G>A p.S704N | Missense Mutation (SNP) | VAF 18/537 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, mutect2
- INTS6 | c.356dup p.E121Gfs*10 | Frame Shift Ins (INS) | VAF 64/336 reads (19%) | called by mutect2, varscan2
- IRF2BPL | c.824del p.P275Lfs*70 | Frame Shift Del (DEL) | VAF 26/170 reads (15%) | called by mutect2, varscan2
- IRGM | c.394A>C p.K132Q | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- IRX1 | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- JAKMIP3 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- KCNH4 | c.2207dup p.G737Wfs*96 | Frame Shift Ins (INS) | VAF 26/196 reads (13%) | called by mutect2, varscan2
- KCNJ3 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KDM6B | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); called by muse, mutect2
- KIF26B | c.3123del p.S1042Afs*90 | Frame Shift Del (DEL) | VAF 46/214 reads (21%) | called by mutect2, varscan2
- KIRREL1 | c.2125C>T p.P709S | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.026); called by muse, mutect2
- KLF2 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2
- KLHL12 | c.1077G>C p.W359C | Missense Mutation (SNP) | VAF 93/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- KLHL17 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KMT2B | c.1259del p.P420Lfs*55 | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, varscan2
- KRTAP19-8 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LATS1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.056); called by muse, mutect2
- LONP1 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- LPA | c.2639C>A p.P880H | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- LPXN | c.622dup p.S208Ffs*14 | Frame Shift Ins (INS) | VAF 46/266 reads (17%) | called by mutect2, varscan2
- LRP1 | c.4640G>C p.G1547A | Missense Mutation (SNP) | VAF 13/263 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- LRRC15 | c.393_395del p.L132del | In Frame Del (DEL) | VAF 35/192 reads (18%) | called by mutect2, varscan2
- LRRC9 | c.603A>T p.Q201H | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2
- LRRTM1 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2
- LYPD6B | c.497C>T p.A166V (on ENST00000409029 / NM_001317004.1; = p.A190V on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- MAB21L2 | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2
- MAGI3 | c.1246del p.S416Afs*21 | Frame Shift Del (DEL) | VAF 66/340 reads (19%) | called by mutect2, varscan2
- MAP1B | c.2046del p.E683Kfs*39 | Frame Shift Del (DEL) | VAF 50/321 reads (16%) | called by mutect2, varscan2
- MAP2 | c.1426T>C p.S476P | Missense Mutation (SNP) | VAF 22/608 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.399); called by muse, mutect2
- MAP3K11 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- MAP4K4 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MARCKSL1 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.429); called by muse, mutect2
- MAST2 | c.4762G>T p.A1588S | Missense Mutation (SNP) | VAF 21/329 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.04); called by muse, mutect2
- MCAT | c.990G>T p.M330I | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.216); called by mutect2, varscan2
- MEFV | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- METTL6 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MEX3C | c.1342A>G p.S448G | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.97); called by muse, mutect2
- MGAM | c.3151C>T p.Q1051* | Nonsense Mutation (SNP) | VAF 70/369 reads (19%) | called by muse, mutect2, varscan2
- MGAT5B | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- MKI67 | c.8626G>A p.V2876I | Missense Mutation (SNP) | VAF 52/335 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- MMP20 | c.153_156del p.N51Kfs*17 | Frame Shift Del (DEL) | VAF 49/302 reads (16%) | called by mutect2, varscan2
- MRGPRE | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MRPL32 | c.279_281del p.R95del | In Frame Del (DEL) | VAF 68/458 reads (15%) | called by mutect2, varscan2
- MSMB | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTNR1B | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2
- MUC5B | c.4306C>A p.P1436T | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MYEF2 | c.1037G>C p.S346T | Missense Mutation (SNP) | VAF 86/494 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYH9 | c.2896_2898del p.K966del | In Frame Del (DEL) | VAF 46/256 reads (18%) | called by mutect2, varscan2
- MYL4 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 33/400 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.339); called by muse, mutect2
- MYO15A | c.2991del p.P998Lfs*60 | Frame Shift Del (DEL) | VAF 30/186 reads (16%) | called by mutect2, varscan2
- MYO9A | c.876T>A p.N292K | Missense Mutation (SNP) | VAF 53/336 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NAGLU | c.1859G>A p.S620N | Missense Mutation (SNP) | VAF 11/265 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.187); called by muse, mutect2
- NBR1 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NCKAP5 | c.2138dup p.L713Ffs*21 | Frame Shift Ins (INS) | VAF 38/298 reads (13%) | called by mutect2, varscan2
- NEB | c.9562G>A p.V3188M | Missense Mutation (SNP) | VAF 22/433 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2
- NEFM | c.2534del p.G845Vfs*10 | Frame Shift Del (DEL) | VAF 60/369 reads (16%) | called by mutect2, varscan2
- NEK1 | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- NEK4 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NEK7 | c.745A>G p.K249E | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- NEMP2 | c.213+1G>T p.X71_splice | Splice Site (SNP) | VAF 26/288 reads (9%) | called by muse, mutect2
- NETO1 | c.1559C>A p.S520Y | Missense Mutation (SNP) | VAF 71/496 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NEUROD1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- NFE2L2 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 24/656 reads (4%) | called by muse, mutect2
- NFIL3 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 34/562 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2
- NOP2 | c.559G>T p.D187Y (on ENST00000322166 / NM_001258308.2; = p.D183Y on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- NPFFR2 | c.518T>C p.M173T | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- NPRL2 | c.970A>G p.R324G | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NUP205 | c.1311G>T p.R437S | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.251); called by muse, mutect2
- NXF1 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 88/376 reads (23%) | called by muse, mutect2, varscan2
- OBSCN | c.10758G>T p.Q3586H | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR10H5 | c.388dup p.L130Pfs*63 | Frame Shift Ins (INS) | VAF 30/210 reads (14%) | called by mutect2, varscan2
- OR1R1P | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- OR2T12 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2
- OR9I1 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- ORC2 | c.629del p.K210Rfs*8 | Frame Shift Del (DEL) | VAF 88/602 reads (15%) | called by mutect2, varscan2
- OSBP | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- OTOGL | c.5726C>T p.P1909L (on ENST00000547103; = p.P1900L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OTUD3 | c.972G>T p.Q324H | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- OTULINL | c.850A>G p.M284V | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PAX7 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAX8 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 68/358 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PCDHGB1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 44/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGC5 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCNX1 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 24/597 reads (4%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- PCNX4 | c.1747del p.S583Lfs*52 (on ENST00000406854 / NM_001330177.2; = p.S349Lfs*52 on NM_022495.5) | Frame Shift Del (DEL) | VAF 96/508 reads (19%) | called by mutect2, varscan2
- PCSK1 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 28/531 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.499); called by muse, mutect2
- PCSK6 | c.468G>T p.Q156H | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDK4 | c.170dup p.L57Ffs*17 | Frame Shift Ins (INS) | VAF 81/494 reads (16%) | called by mutect2, varscan2
- PECR | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 83/376 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PEG10 | c.866G>A p.R289H (on ENST00000482108 / NM_001040152.2; = p.R323H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PER3 | c.2147A>G p.K716R | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PEX11B | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- PFKFB1 | c.87_89del p.R31del | In Frame Del (DEL) | VAF 50/260 reads (19%) | called by mutect2, varscan2
- PINK1 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2
- PLCL2 | c.1595T>C p.V532A (on ENST00000615277 / NM_001144382.2; = p.V406A on NM_015184.5) | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- PLD3 | c.487A>G p.I163V | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2
- PLPPR3 | c.1852G>A p.G618S (on ENST00000520876 / NM_001270366.2; = p.G646S on NM_024888.2) | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- PML | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1523dup p.N508Kfs*24 | Frame Shift Ins (INS) | VAF 110/528 reads (21%) | called by mutect2, varscan2
- POLR3A | c.2336C>T p.T779I | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPFIA4 | c.2423G>T p.R808L (on ENST00000447715; = p.R809L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.142); called by mutect2, varscan2
- PPP2CA | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- PREP | c.562G>T p.G188* (on ENST00000369110; = p.G254* on NM_002726.5) | Nonsense Mutation (SNP) | VAF 72/516 reads (14%) | called by muse, mutect2, varscan2
- PRKCQ | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 58/445 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- PRMT6 | c.38del p.G13Afs*48 | Frame Shift Del (DEL) | VAF 47/221 reads (21%) | called by mutect2, varscan2
- PROZ | c.817T>A p.C273S | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- PRR23C | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- PSIP1 | c.158dup p.L53Ffs*13 | Frame Shift Ins (INS) | VAF 22/127 reads (17%) | called by mutect2, varscan2
- PSMD1 | c.1574del p.N525Mfs*28 | Frame Shift Del (DEL) | VAF 71/442 reads (16%) | called by mutect2, varscan2
- PSME1 | c.645G>T p.M215I | Missense Mutation (SNP) | VAF 17/495 reads (3%) | SIFT tolerated (0.73); PolyPhen benign (0.033); called by muse, mutect2
- PTBP1 | c.209T>G p.V70G | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- PTPRN2 | c.2155del p.V719Cfs*12 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by mutect2, varscan2
- PXN | c.978del p.P328Rfs*18 (on ENST00000228307 / NM_001080855.3; = p.P294Rfs*18 on NM_002859.4) | Frame Shift Del (DEL) | VAF 40/207 reads (19%) | called by mutect2, varscan2
- RAB3A | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2
- RAD51AP2 | c.2076G>A p.M692I | Missense Mutation (SNP) | VAF 33/357 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 92/530 reads (17%) | called by mutect2, varscan2
- RAPH1 | c.3227del p.P1076Lfs*41 | Frame Shift Del (DEL) | VAF 57/287 reads (20%) | called by mutect2, varscan2
- RBPJL | c.1467del p.E490Sfs*33 | Frame Shift Del (DEL) | VAF 35/228 reads (15%) | called by mutect2, varscan2
- RGS2 | c.364del p.T122Pfs*19 | Frame Shift Del (DEL) | VAF 74/547 reads (14%) | called by mutect2, varscan2
- RHOBTB2 | c.1916A>G p.Y639C | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RLF | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.145); called by muse, mutect2
- RNASET2 | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 25/426 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2
- RNF20 | c.1067T>C p.V356A | Missense Mutation (SNP) | VAF 49/347 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RNF208 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RORA | c.496C>T p.Q166* (on ENST00000335670 / NM_134261.3; = p.Q191* on NM_002943.3) | Nonsense Mutation (SNP) | VAF 17/458 reads (4%) | called by muse, mutect2
- RSF1 | c.4295T>C p.V1432A | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RYR3 | c.65T>C p.V22A | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2
- SACS | c.1181T>C p.V394A | Missense Mutation (SNP) | VAF 55/409 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SALL3 | c.3349T>C p.S1117P | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
474 further variants in this file (126 protein-altering or splice-affecting, 308 silent, 40 other) are not listed here.
